Somatic mutation profile of tumor specimen 0DJO5K from CCDI case PBBXAU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 2.6 years (962 days).
Specimen 0DJO5K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 121a78c5-d6a9-4b46-a9a4-37c3404f0d77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b60a009b-f1f2-416c-b966-5fb43a514f3f

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NLGN4X | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760432673, COSV52002990; called by muse, mutect2, varscan2
- CD55 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 130/544 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.4523G>A p.C1508Y | Missense Mutation (SNP) | VAF 129/608 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA2 | c.2196del p.G733Afs*65 | Frame Shift Del (DEL) | VAF 404/706 reads (57%) | called by mutect2, pindel, varscan2
- TNFSF12 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 124/450 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.396); called by muse, mutect2
- LSM10 | c.264G>A p.V88= | Silent (SNP) | VAF 171/376 reads (45%) | called by muse, mutect2, varscan2
- ZNF106 | c.666C>T p.N222= | Silent (SNP) | VAF 94/306 reads (31%) | catalogued as rs751837308, COSV55521359; called by muse, mutect2, varscan2
- C20orf197 | n.636G>T | RNA (SNP) | VAF 98/239 reads (41%) | called by muse, mutect2, varscan2
- CYBC1 | c.128-50G>A | Intron (SNP) | VAF 8/75 reads (11%) | catalogued as rs750765186; called by muse, mutect2, varscan2
- OSR2 | c.-114-500G>A | Intron (SNP) | VAF 142/620 reads (23%) | called by muse, mutect2, varscan2
